Gene-level copy-number profile of tumor specimen TCGA-CV-6441-01A from TCGA case TCGA-CV-6441, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.3 years (22,025 days).
Specimen TCGA-CV-6441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6383423b-7e0d-4e1c-a040-b7c38544505c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6441-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d11145c3-bb0f-4d09-a691-5ac2188dfb37

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 2,546; copy number 2: 10,128; copy number 3: 13,832; copy number 4: 28,892; copy number 5: 3,196; copy number 6: 42; copy number 7: 542; copy number 8: 46; copy number 9: 82; copy number 10: 2; copy number 11: 39; copy number 12: 248; copy number 13: 31; copy number 14: 193; copy number 15: 150; copy number 16: 130; copy number 17: 19; copy number 20: 12; copy number 21: 20; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6441-01A-11D-1682-01): tumor purity 0.7, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,918,709–4,046,722, 2 genes: AC023480.1, PNPT1P1.
- chr3:41,194,741–41,962,130, 4 genes (within-gene range 0–2): CTNNB1, ULK4, AC099537.1, RN7SKP58.
- chr9:14,204,248–14,205,039, 1 gene: AL441963.1.
- chr9:19,926,094–22,214,672, 68 genes (broad region; genes not listed).
- chr9:96,450,169–96,655,317, 3 genes (within-gene range 0–5): HABP4, CDC14B, PRXL2C.
- chr9:136,483,495–136,546,048, 3 genes (within-gene range 0–5): C9orf163, NOTCH1, MIR4673.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 919 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–34,124,528, 517 genes, copy number 12–16 (within-gene range 7–16) (broad region; genes not listed).
- chr5:34,105,750–45,895,970, 192 genes, copy number 12 (broad region; genes not listed).
- chr7:83,955,777–85,636,344, 13 genes, copy number 14–20: SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr7:112,450,460–112,490,941, 1 gene, copy number 10 (within-gene range 7–10): AC005192.1.
- chr7:112,480,853–112,491,062, 1 gene, copy number 10: LSMEM1.
- chr8:38,163,335–38,176,730, 1 gene, copy number 21 (within-gene range 2–21): LSM1.
- chr8:38,176,533–43,674,591, 134 genes, copy number 9–21 (broad region; genes not listed).
- chr18:47,390–2,655,395, 58 genes, copy number 11–17: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2.
- chr20:1,561,385–1,620,061, 2 genes, copy number 24 (within-gene range 3–24): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
